Somatic mutation profile of tumor specimen TARGET-40-PAPXGT-01A (aliquot TARGET-40-PAPXGT-01A-01D) from TARGET case TARGET-40-PAPXGT, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 11.4 years (4,172 days).
Specimen TARGET-40-PAPXGT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8623fa6f-ca39-41e1-851a-c2f2d83fa70a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAPXGT-10A (Blood Derived Normal), aliquot TARGET-40-PAPXGT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30cbb010-f803-42fe-8b69-fa34e12deaaf

The open-access MAF lists 43 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 9, Intron 5, Nonsense Mutation 4, 3'UTR 2, 5'UTR 2, Splice Region 2, Frame Shift Del 1, 5'Flank 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC100868.1 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 107/363 reads (29%) | catalogued as COSV51841790, COSV99225412; called by muse, mutect2, varscan2
- ACTB | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 61/239 reads (26%) | catalogued as COSV59321121; called by muse, mutect2, varscan2
- C7 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775095625, COSV57472920; called by muse, mutect2, varscan2
- CTSV | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774981893, COSV52344228; called by muse, mutect2, varscan2
- EHD3 | c.1346A>G p.D449G | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1022251078, COSV100434671; called by muse, mutect2, varscan2
- HECW1 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.439); catalogued as rs1313411241, COSV67831345; called by muse, varscan2
- KMT2B | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.973); catalogued as rs748562206; called by muse, mutect2, varscan2
- LRP2 | c.1549G>A p.V517M | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs770524674; called by muse, mutect2, varscan2
- PTEN | c.750_751del p.C250Wfs*2 | Frame Shift Del (DEL) | VAF 40/120 reads (33%) | catalogued as rs780264945; called by pindel, varscan2
- RABL3 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 96/195 reads (49%) | catalogued as rs977481540; called by muse, mutect2, varscan2
- SGSM1 | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.397); catalogued as COSV68513910; called by muse, mutect2, varscan2
- TRAF7 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs775280844; called by muse, mutect2, varscan2
- TYW1 | c.1744G>A p.V582M | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.106); catalogued as rs754509946, COSV62754069; called by muse, mutect2, varscan2
- CACNA1I | c.2584G>C p.V862L | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- FBXO15 | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- MUC5B | c.17070G>A p.K5690= | Splice Region (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- OR8I2 | c.557T>G p.L186R | Missense Mutation (SNP) | VAF 59/212 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RLF | c.5596A>G p.K1866E | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SLC43A1 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | called by muse, mutect2, varscan2
- TKTL2 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UCHL3 | c.609+7G>T | Splice Region (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- ZNF519 | c.100_102del p.L34del | In Frame Del (DEL) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- ZNF649 | c.292C>A p.L98M | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- GSPT2 | c.900T>C p.G300= | Silent (SNP) | VAF 18/448 reads (4%) | catalogued as COSV61214968; called by muse, mutect2
- MSC | c.546C>T p.F182= | Silent (SNP) | VAF 102/370 reads (28%) | catalogued as COSV100335689; called by muse, mutect2, varscan2
- MYO16 | c.1767C>A p.G589= | Silent (SNP) | VAF 35/99 reads (35%) | called by muse, mutect2, varscan2
- NCBP1 | c.555C>T p.Y185= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs1477848847, COSV100912601; called by muse, mutect2, varscan2
- OR11H2 | c.741T>C p.S247= (on ENST00000556246; = p.S258= on NM_001197287.1) | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as rs1169234887; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.591C>T p.D197= (on ENST00000259318 / NM_001136562.3; = p.D428= on NM_007203.5) | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as rs377038997; called by muse, mutect2, varscan2
- PIN4 | c.150C>T p.D50= (on ENST00000664196; = p.D25= on NM_006223.4) | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs1184254268; called by muse, mutect2, varscan2
- RANBP2 | c.2820T>C p.G940= | Silent (SNP) | VAF 35/112 reads (31%) | called by muse, mutect2, varscan2
- TINF2 | c.1242G>A p.Q414= | Silent (SNP) | VAF 47/203 reads (23%) | called by muse, mutect2, varscan2
- AGBL1 | c.2374+9A>G | Intron (SNP) | VAF 31/127 reads (24%) | called by muse, mutect2, varscan2
- AP000533.1 | n.282C>G | RNA (SNP) | VAF 20/146 reads (14%) | called by muse, varscan2
- ARFGEF3 | c.*4818T>C | 3'UTR (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- ARVCF | c.1961-26G>A | Intron (SNP) | VAF 20/62 reads (32%) | catalogued as rs755976851; called by muse, mutect2, varscan2
- CYP2C9 | c.169-128A>C | Intron (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- EIF4A2 | c.-3A>T | 5'UTR (SNP) | VAF 47/146 reads (32%) | called by muse, mutect2, varscan2
- GMNC | c.268-146A>T | Intron (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- GPATCH3 | c.*321G>C | 3'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2
- LLGL2 | c.827-88G>A | Intron (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- POU3F2 | c.-113T>A | 5'UTR (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2
- SAA1 | chr11:18262369 C>T | 5'Flank (SNP) | VAF 58/209 reads (28%) | called by muse, mutect2, varscan2
